TCGA case TCGA-AA-A01R — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97f6c8d3-09a0-4128-8f10-41e736648a5f

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 47 years; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 47.3 years (17,289 days); Year of diagnosis: 2004; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,065 days (2.9 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 9; Lymph nodes tested: 19; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 60 days; Days to treatment end: 820 days (2.2 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan + Leucovorin Calcium; Days to treatment start: 669 days (1.8 years); Days to treatment end: 820 days (2.2 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 881 days (2.4 years); Days to treatment end: 943 days (2.6 years); Treatment dose: 50 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Primary Tumor Field.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 49.0 years (17,897 days); Days to diagnosis: 608 days (1.7 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 29 days; Disease response: With Tumor.
- Day 608 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 608 days (1.7 years).
- Days to follow up: 1,065 days (2.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 1.83 ng/mL.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-A01R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 920 mg.
  Slide TCGA-AA-A01R-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 17; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
  Slide TCGA-AA-A01R-01A-01-BS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 12; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-AA-A01R-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-A01R-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 240 mg.
  Slide TCGA-AA-A01R-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 45; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A01R-11A-01-BS1: Section location: Bottom; Percent tumor cells: 0; Percent normal cells: 100; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 1.83; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 2: Pharmaceutical therapy drug name: Folinic acid.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: Yes; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,065 days; disease-specific survival: no event (censored), 1,065 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 608 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-A01R-01A-21D-A080-01): tumor purity 0.63, ploidy 2.09, whole-genome doublings 0.
